MMRF case MMRF_2487 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/75eb7a5c-f443-412d-8e8f-4b83606ff716

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,124 days); ISS stage: II; Days to last known disease status: 632 days (1.7 years); Days to last follow up: 632 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 258 days; Days to treatment end: 259 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days; Days to treatment end: 260 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): Immunoglobulin G 7.96 g/L; Immunoglobulin A 20.7 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 12 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 93 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.8 mg/dL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 191 (ECOG 0): M Protein 1.8 g/dL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.57 mmol/L.
- Day 281: Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 374 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 366 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.15 mg/dL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.46 mmol/L.
- Day 449: Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 547: Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 632: Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 3.8 mmol/L.

Other clinical attributes
- Day 1: Weight: 84 kg; Height: 185 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2487_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2487_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
